Gene-level copy-number profile of tumor specimen TCGA-HV-A5A6-01A from TCGA case TCGA-HV-A5A6, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 65.8 years (24,025 days).
Specimen TCGA-HV-A5A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.ddc75d62-74c7-43d0-84c6-d5a30ec54b68.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HV-A5A6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27d0b341-51d7-400c-9b82-38e38fb2564c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 759; copy number 2: 7,150; copy number 3: 11,541; copy number 4: 34,173; copy number 5: 1,920; copy number 6: 1,633; copy number 7: 2,358; copy number 8: 37; copy number 9: 89; copy number 10: 55; copy number 11: 45; copy number 13: 5; copy number 15: 23; copy number 39: 25; copy number 42: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HV-A5A6-01A-11D-A26H-01): tumor purity 0.48, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 248 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:34,189,780–35,148,610, 30 genes, copy number 13–39: KRT18P9, CYCSP55, HMGA1, MIR6835, SMIM29, AL354740.1, RPL35P2, NUDT3, RPS10-NUDT3, RPS10, PACSIN1, SPDEF, IFITM3P3, ILRUN, RPL7P25, RN7SL200P, AL031577.1, AL451165.2, AL451165.1, AL139100.1, SNRPC, UHRF1BP1, Y_RNA, RNY3P15, TAF11, ANKS1A, HSPE1P11, AL591002.1, AL138721.1, TCP11.
- chr6:35,473,597–36,197,205, 23 genes, copy number 15 (within-gene range 3–15): TEAD3, TULP1, AL033519.4, AL033519.3, FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690, AL157823.2, ARMC12, AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1, SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1.
- chr7:86,643,914–87,480,435, 15 genes, copy number 9: GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4.
- chr7:87,521,461–87,522,410, 1 gene, copy number 9: HNRNPA1P9.
- chr7:90,245,174–93,226,469, 51 genes, copy number 11–42: CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2.
- chr7:97,117,698–97,437,896, 4 genes, copy number 9: SDHAF3, HMGB3P21, AC073900.1, AP1S2P1.
- chr13:18,467,172–20,525,873, 69 genes, copy number 9 (broad region; genes not listed).
- chr18:3,770,017–4,024,150, 6 genes, copy number 10: AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr18:20,946,906–23,026,488, 49 genes, copy number 10: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P.

Autosomal genes at a single copy (total copy number 1): 759. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
